Gene-level copy-number profile of tumor specimen TCGA-AR-A0TT-01A from TCGA case TCGA-AR-A0TT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.9 years (19,679 days).
Specimen TCGA-AR-A0TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2b2697ab-f5e8-476f-b043-62ecdf1ca8b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6dbee44e-0da3-46ae-bfbe-8cae16f173e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 542; copy number 1: 7,783; copy number 2: 22,534; copy number 3: 16,900; copy number 4: 7,382; copy number 5: 1,576; copy number 6: 639; copy number 7: 406; copy number 8: 451; copy number 9: 341; copy number 10: 198; copy number 11: 118; copy number 12: 150; copy number 13: 16; copy number 14: 132; copy number 15: 76; copy number 16: 90; copy number 17: 13; copy number 18: 4; copy number 19: 6; copy number 20: 62; copy number 21: 97; copy number 22: 100; copy number 28: 48; copy number 29: 82; copy number 31: 10; copy number 33: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TT-01A-31D-A087-01): tumor purity 0.39, ploidy 2.32, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 542 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:182,143,987–182,803,024, 1 gene (within-gene range 0–7): TENM3.
- chr4:182,548,659–188,161,157, 128 genes (broad region; genes not listed).
- chr8:150,584–4,994,972, 61 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:14,084,845–15,238,431, 1 gene (within-gene range 0–2): SGCZ.
- chr8:14,309,033–33,361,415, 351 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,617 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,813,225–152,776,728, 165 genes, copy number 5–14 (broad region; genes not listed).
- chr1:153,890,595–156,177,752, 135 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:158,398,522–158,977,059, 28 genes, copy number 6: OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1.
- chr1:160,796,074–163,923,873, 104 genes, copy number 5–10 (broad region; genes not listed).
- chr1:180,509,380–196,609,225, 202 genes, copy number 6–17 (broad region; genes not listed).
- chr1:199,371,877–203,744,081, 124 genes, copy number 7 (broad region; genes not listed).
- chr1:206,470,476–206,970,625, 22 genes, copy number 12: IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D, DYRK3-AS1, DYRK3, MAPKAPK2, AL591846.1, Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR.
- chr4:122,923,070–130,967,575, 73 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr4:168,828,919–173,409,559, 53 genes, copy number 5 (within-gene range 4–5): AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512, AC074255.1, HSP90AA6P, LINC02382, AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431, AC034159.1, AC092639.1, MIR6082, LINC02504, AC074254.2, LINC02174, AC074254.1, GALNTL6, AC108064.1, AC105285.1, RN7SL253P, GALNT7, MIR548T, AC097534.1, HMGB2, SAP30-DT, SAP30, SCRG1, AC093849.4.
- chr4:176,213,673–180,117,163, 28 genes, copy number 6–8 (within-gene range 4–8): ASB5, SPCS3-AS1, SPCS3, AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P, AC095041.1, RNA5SP173, AC017087.1, AC018710.1, AC020551.1, AC021193.1, AC108169.1, AC096747.1.
- chr5:28,213,359–40,067,200, 191 genes, copy number 5–6 (broad region; genes not listed).
- chr6:78,867,551–79,703,655, 20 genes, copy number 10 (within-gene range 3–10): IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2.
- chr6:92,387,841–121,858,768, 367 genes, copy number 10–33 (broad region; genes not listed).
- chr7:63,699,390–67,302,419, 155 genes, copy number 5 (broad region; genes not listed).
- chr8:81,439,436–111,757,710, 480 genes, copy number 5–21 (broad region; genes not listed).
- chr8:117,128,455–121,994,185, 49 genes, copy number 5–8 (within-gene range 4–8): AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855.
- chr10:66,926,036–71,077,810, 102 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr10:75,742,740–84,294,659, 129 genes, copy number 6–10 (broad region; genes not listed).
- chr10:129,467,190–133,761,125, 102 genes, copy number 6–16 (broad region; genes not listed).
- chr11:73,787,872–75,351,705, 64 genes, copy number 5 (broad region; genes not listed).
- chr11:75,759,512–79,989,630, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:85,628,573–89,065,945, 69 genes, copy number 6 (broad region; genes not listed).
- chr12:65,418,731–70,920,738, 114 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:89,991,831–91,354,579, 20 genes, copy number 5: PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr14:25,647,304–32,882,830, 99 genes, copy number 9–14 (within-gene range 2–14) (broad region; genes not listed).
- chr15:59,659,146–61,240,331, 31 genes, copy number 6–10 (within-gene range 3–10): BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.2, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1, AC012404.2, AC107905.1.
- chr15:79,743,311–80,186,946, 24 genes, copy number 14: AC026826.3, AC026826.1, AC026826.2, RNU6-667P, AC021483.1, MTHFS, AC021483.2, ST20-MTHFS, AC015871.4, AC015871.6, ST20, AC015871.7, AC015871.3, ST20-AS1, AC015871.8, AC015871.1, BCL2A1, AC015871.2, AC015871.5, AC092701.1, Metazoa_SRP, ZFAND6, FAH, AC087761.1.
- chr15:82,531,653–85,794,925, 113 genes, copy number 11–15 (broad region; genes not listed).
- chr15:89,518,523–90,717,141, 61 genes, copy number 20 (within-gene range 1–20) (broad region; genes not listed).
- chr15:91,094,847–95,169,864, 65 genes, copy number 13–31 (within-gene range 1–31) (broad region; genes not listed).
- chr15:96,756,987–101,933,350, 124 genes, copy number 12–29 (broad region; genes not listed).
- chr16:25,111,731–32,946,392, 391 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr17:26,981,694–31,382,116, 240 genes, copy number 9 (broad region; genes not listed).
- chr17:36,486,629–38,323,217, 53 genes, copy number 9 (within-gene range 2–9): ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45.
- chr17:59,565,558–60,666,280, 48 genes, copy number 14 (within-gene range 3–14): DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:73,831,572–74,623,738, 25 genes, copy number 5–9: AC125421.2, AC137735.1, AC137735.3, AC137735.2, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1, CD300E.
- chr17:77,722,872–78,425,114, 27 genes, copy number 5: LINC01987, LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1.
- chr19:3,314,403–4,127,732, 43 genes, copy number 5 (within-gene range 2–5): NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY, RN7SL202P, NMRK2, DAPK3, MIR637, EEF2, SNORD37, PIAS4, ZBTB7A, AC016586.1, MAP2K2, Metazoa_SRP.
- chr19:23,897,321–27,984,984, 25 genes, copy number 6 (within-gene range 4–6): AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1.
- chr19:55,090,914–58,605,223, 257 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
